Surgical pathology report (de-identified scan), TCGA case TCGA-EJ-A8FU, project TCGA-PRAD (Prostate Adenocarcinoma), tissue source site University of Pittsburgh, specimen TCGA-EJ-A8FU-01A (Primary Tumor).

[page 1 of 2]
Collection Date:

FINAL DIAGNOSIS:

PART 1: LYMPH NODES, RIGHT PELVIC, EXCISION -
NO EVIDENCE OF NEOPLASIA IN SIXTEEN (16) LYMPH NODES EXAMINED.

PART 2: LYMPH NODES, LEFT PELVIC, EXCISION -
NO EVIDENCE OF NEOPLASIA IN THIRTEEN (13) LYMPH NODES EXAMINED.

PART 3: SOFT TISSUE, ANTERIOR FAT PAD, EXCISION -
BENIGN FIBROADIPOSE TISSUE, NEGATIVE FOR MALIGNANCY.

Per TSS, Gleason is 4+5=9.
BCR.

PART 4: PROSTATE AND BILATERAL SEMINAL VESICLES, RADICAL PROSTATECTOMY -
A. INVASIVE POORLY DIFFERENTIATED ADENOCARCINOMA, GLEASON SCORE 5 + 3 = 8 WITH TERTIARY GLEASON PATTERN 4.
B. THE CARCINOMA INVOLVES BOTH THE RIGHT AND LEFT LOBES AND HAS A GREATEST NODULAR DIAMETER OF 1.2 CM.
C. THE CARCINOMA INVOLVES APPROXIMATELY 5% OF THE EXAMINED PROSTATE VOLUME.
D. THE CARCINOMA SHOWS FOCAL EXTRACAPSULAR EXTENSION.
E. THE EXTRACAPSULAR EXTENSION IS SEEN IN THE POSTERIOR LEFT MID REGION (SLIDE 4Z).
F. BILATERAL SEMINAL VESICLES ARE FREE OF CARCINOMA.
G. ALL EXAMINED SURGICAL RESECTION MARGINS ARE FREE OF CARCINOMA.
H. PERINEURAL INVASION IS IDENTIFIED.
I. NO ANGIOLYMPHATIC INVASION IS IDENTIFIED.
J. HIGH-GRADE PROSTATIC INTRAEPITHELIAL NEOPLASIA IS IDENTIFIED.
K. PATHOLOGIC TNM STAGE: pT3a N0 MX.
L. TNM HISTOLOGIC GRADE = G4.
M. BENIGN PROSTATIC HYPERTROPHY AND CHRONIC MODERATELY ACTIVE PROSTATITIS ARE NOTED.

PART 5: SOFT TISSUE, RIGHT, CORD, EXCISION -
LIPOMA (5.0 CM).

CASE SYNOPSIS:

SYNOPTIC DATA - PRIMARY PROSTATE TUMORS:
CLINICAL DATA: PSA value: 5.1
INVASIVE CA IDENTIFIED?: Yes
TUMOR HISTOLOGY: Adenocarcinoma NOS
PRIMARY GLEASON GRADE: 5
SECONDARY GLEASON GRADE: 3
GLEASON SUM SCORE: 8
GLEASON 4/5 PERCENTAGE: 40%
WEIGHT OF PROSTATE: 41.86gm
TUMOR SIZE: Maximum dimension: 1.2 cm
LOBE LATERALITY: Right and Left Lobes
PERCENT OF SPECIMEN INVOLVED BY TUMOR: 5 - 25%
MULTIFOCAL DISEASE: Yes
HIGH GRADE PIN: Yes - NOS
EXTRAPROSTATIC EXTENSION: Yes - Focal
PERINEURAL INVASION: Yes
ANGIOLYMPHATIC INVASION: No
SEMINAL VESICLE INVASION: No
SURGICAL MARGIN INVOLVEMENT: All surgical margins free of tumor
LYMPH NODES EXAMINED: 29

LYMPH NODES POSITIVE: 0
T STAGE, PATHOLOGIC: pT3a
N STAGE, PATHOLOGIC: pN0
M STAGE, PATHOLOGIC: pMX
HISTOLOGIC GRADE: G3-4, Poorly differentiated/undifferentiated

ICD-O-3
Adenocarcinoma NOS
8140/3
Site: Prostate NOS
C61.9
JY 11/7/14

ICD-O Discrepancy		
Discrepancy Primary Site		
Case is (cl c/s):		

10/24/13

[page 2 of 2]
TCGA Pathologic Diagnosis Discrepancy Form 4.05 ☒

Study Subject ID:		Person ID:	N/A
Study/Site:	TCGA Prostate adenocarcinoma - (Prostate adenocarcinoma)	Age:	N/A
Event:	PathDiscrepancy	Date of Birth:	
Interviewer:		Sex:	M

Tumor Identifier Provided on Initial Case Quality Control Form	Provide the tumor identifier documented on the initial case quality control form for this case.
Pathologic Diagnosis Provided on Initial Pathology Report	invasive prostatic adenocarcinoma Provide the diagnosis/ histologic subtype(s) documented on the initial pathology report for this case. If the histology for this case is mixed, provide all listed subtypes.
Histologic features of the sample provided for TCGA, as reflected on the CQCF	NA Provide the histologic features selected on the TCGA Case Quality Control Form completed for this case.
Discrepancy between Pathology Report and Case Quality Control Form	
Provide the reason for the discrepancy between the pathology report and the TCGA Case Quality Control Form	specimen submitted has a different gleason score Provide a reason describing why the diagnosis on the initial pathology report for this case is not consistent with the diagnosis selected on the TCGA Case Quality Control Form.
Name of TSS Reviewing Pathologist or Biorepository Director	Provide the name of the pathologist who reviewed this case for TCGA.

GLEASON SCORE OF TISSUE SUBMITTED IS 4+5=9
GLEASON SCORE OF CASE IS 5+3=8

Source: NCI Genomic Data Commons file 7cdb4cf0-bada-4d49-9c95-515683f9c42f (TCGA-EJ-A8FU.613A9A17-E6E6-4A15-A06A-FB3D91D7459A.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).